Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4912, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4912-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4912

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 3. (15.0 CM)

No invasion of renal sinus adipose tissue or renal vein.

Vascular, ureteral, and soft tissue margins of resection free of tumor.

Adrenal gland, free of tumor.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A radical nephrectomy specimen (22.0 x 13.0 x 9.0 cm) including the left kidney (15.5 x 11.5 x 7.0 cm), a segment of renal artery, the renal vein, and ureter (12.0 cm in length and 0.3 cm average diameter) and the adrenal gland (5.5 x 0.8 x 0.7 cm).

There is a lobulated, multinodular mass measuring 15.0 x 9.0 x 5.8 cm in the lower and mid poles of the kidney towards the lateral aspect. The tumor is bright yellow with a central area of myxoid change/degeneration representing 20% of the tumor. The tumor is eccentrically placed towards the lateral portion of the kidney and focal areas of tumor involve the perirenal fat. The tumor is less than 0.1 cm from the Gerota's fascia (overlying Gerota's fascia appears intact).

The adjacent kidney parenchyma shows a 2.5 x 2.5 x 1.8 cm well circumscribed cyst filled with necrotic green-tan material. The cyst is located towards the inferior and medial aspect of the kidney, 0.6 cm from the mass. The pelvicalyceal system is smooth and devoid of any lesions. No lymph nodes are identified in the hilum of the kidney. Serial cross sections of the left adrenal gland show unremarkable cortex and medulla. Portions of the tumor have been submitted for possible electron microscopy and cytogenetics. Majority of the tumor has been submitted for a vaccine protocol.

INK CODE: Black - Gerota's fascia.

SECTION CODE: A1, ureter, renal artery, and renal vein margin; A2, representative sections from the adrenal gland; A3, tumor in relationship to renal sinus; A4-A5, tumor with overlying inked Gerota's fascia and renal fat; A6-A8, representative sections of the cyst towards the inferior pole; A9, tumor with overlying capsule; A10-A13, representative sections from different areas of the tumor; A14, tumor with surrounding renal parenchyma; A15, tumor with surrounding renal parenchyma; A16, representative section of renal sinus; A17, representative section of normal kidney. [REDACTED]

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file f49e4e53-41c9-4892-be53-5ecde0182c03 (TCGA-CJ-4912.AD1E7A08-1C34-49EE-8F72-A233AA5AE147.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).